Somatic mutation profile of tumor specimen 0DZY58 from CCDI case PBCUIN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZY58: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2071eda0-59a8-406b-91b0-a5914f7dfb38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZY6A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cba8b920-fe50-4261-bd6b-4c1f34253c1a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELF4 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.041); catalogued as rs1404064211, COSV57453222; called by muse, mutect2
- MFSD2B | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOSPD2 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); called by muse, mutect2
- IGFL2 | c.*68A>C | 3'UTR (SNP) | VAF 21/249 reads (8%) | called by muse, mutect2
